Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A4BR, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A4BR-01A (Primary Tumor).

[page 1 of 4]
Male

SURGICAL PATHOLOGY

Status: Final result MyChart: Not Released

Surgical Pathology

Department of Pathology

Surgical Pathology Laboratory

Surgical Pathology Report

Specimen Date:

In Lab Date:

Report Date:

[REDACTED]

CLINICAL INFORMATION:

Prostate ca.

Specimen submitted: A. Distal apical margin (fs); B. Left apical margin (fs); C. Right apical margin (fs); D. Anterior apical margin (fs); E. Posterior apical margin (fs); F. Anterior prostatic fat; G. Prostate and seminal vesicles; H. Pelvic lymph nodes

INTRAOPERATIVE DIAGNOSIS:

- A. Frozen section diagnosis: Fibromuscular tissue and benign prostatic glands.
- B. Frozen section diagnosis: Fibromuscular tissue and nerve. No prostatic glands or carcinoma seen.
- C. Frozen section diagnosis: Fibromuscular tissue and nerve. No prostatic glands or carcinoma seen.
- D. Frozen section diagnosis: Fibromuscular tissue, nerve and benign prostatic glands.
- E. Frozen section diagnosis: Fibromuscular tissue and nerve. No prostatic glands or carcinoma seen.

Reported to

(A-E)

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "distal apical margin," and consists of a 0.3 x 0.2 x 0.1 cm piece of red-tan soft tissue. The specimen is 100% frozen and 100% submitted. Summary of sections: AFSC.

B. Received fresh, the specimen is labeled "left apical margin,"

COF: adenocarcinoma, acinar 8/5/03
Path: adenocarcinoma, NOS 8/14/03
Site: Prostate, NOS CL1.9
No 9/24/12

1CD-0-3

[page 2 of 4]
and consists of a 0.4 x 0.3 x 0.2 cm piece of red-tan soft tissue. The specimen is 100% frozen and 100% submitted. Summary of sections: BFSC.

C. Received fresh, the specimen is labeled "right apical margin," and consists of a 0.4 x 0.3 x 0.2 cm piece of red-tan soft tissue. The specimen is 100% frozen and 100% submitted. Summary of sections: CFSC.

D. Received fresh, the specimen is labeled "anterior apical margin," and consists of a 0.4 x 0.2 x 0.1 cm piece of red-tan soft tissue. The specimen is 100% frozen and 100% submitted. Summary of sections: DFSC.

E. Received fresh, the specimen is labeled "posterior apical margin," and consists of a 0.3 x 0.2 x 0.2 cm piece of red-tan soft tissue. The specimen is 100% frozen and 100% submitted. Summary of sections: EFSC.

F. Received fresh, the specimen is labeled "anterior prostatic fat," and consists of a 2.5 x 1.5 x 0.5 cm aggregate of lymph nodes and fibrofatty tissue. The specimen is 100% submitted. Summary of sections: F1.

G. Received fresh, the specimen is labeled "prostate and seminal vesicles", and consists of a 57.3 gram radical prostatectomy specimen including a 6.0 x 5.0 x 3.5 cm prostate, a 4.0 x 2.0 x 1.0 cm left seminal vesicle, a 3.0 x 0.5 x 0.5 cm left vas deferens, a 4.5 x 2.0 x 1.0 cm right seminal vesicle and a 3.5 x 0.5 x 0.5 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to E respectively. On sectioning, multiple nodular and cystic areas are seen. The prostate is submitted in alternate sections. Summary of sections: G1- right seminal vesicle; G2- left seminal vesicle; G3- right anterior base margin; G4- right posterior base margin; G5- left anterior base margin; G6- left posterior base margin; G7- right anterior apex margin; G8- right posterior apex margin; G9- left anterior apex margin; G10- left posterior apex margin; G11- RAA; G12- RPA; G13- LAA; G14- LPA; G15- RAC; G16- RMC; G17- RPC; G18- LAC; G19- LMC; G20- LPC; G21- RAE; G22- RME; G23- RPE; G24- LAE; G25- LME; G26- LPE. Note: (R=Right; L=Left; A=Anterior; P=posterior; M=mid).

H. Received fresh, the specimen is labeled "pelvic lymph nodes," and consists of a 4.0 x 3.0 x 1.0 cm aggregate of lymph nodes and fibrofatty tissue. The specimen is 100% submitted. Summary of sections: H1- two lymph nodes bisected; H2- one lymph node bisected; H3- two lymph nodes bisected; H4-H6- pelvic lymph nodes.

DIAGNOSIS:

A. Prostate, distal apical margin (biopsy):
Fibromuscular tissue and benign prostatic glands.

B. Prostate, left apical margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma seen.

[page 3 of 4]
C. Prostate, right apical margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma seen.

D. Prostate, anterior apical margin (biopsy):
Fibromuscular tissue, nerve and benign prostatic
glands.

E. Prostate, posterior apical margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma seen.

F. Anterior prostatic fat (biopsy):
Benign adipose tissue and blood vessels.

G. Prostate and seminal vesicles (excision):
Prostatic adenocarcinoma, Gleason score 9(4+5),
bilateral.
Left seminal vesicle involved by carcinoma.
Multifocal extraprostatic extension, left
posterior (G2, G6, G10, G14, G19, G20, G26).
Focal invasion into wall of periprostatic vein (G20).
Right seminal vesicle is negative for carcinoma.
Surgical margins are negative for carcinoma.
Please see staging summary.

H. Lymph nodes, pelvic (biopsy):
One of eleven lymph nodes, positive for metastatic
carcinoma (1/11).

SYNOPTIC DIAGNOSIS:

Histologic Type:	Adenocarcinoma
(conventional, not otherwise specified)	
	Primary Pattern: Grade 4
	Secondary Pattern: Grade 5
	Total Gleason Score: 9
Tumor Quantitation:	Proportion (percent) of
prostatic tissue involved by tumor: 25%	
Pathologic Staging (pTNM):	pT3b: Seminal vesicle
invasion	
	pN1: Metastasis in
regional lymph node or nodes	
nodes examined: 11	Number of regional lymph
nodes involved: 1	Number of regional lymph
	pMX: Distant metastasis
cannot be assessed	
Margins:	Margins uninvolved by
invasive carcinoma	
Extraprostatic Extension:	Present
	Multifocal present
Seminal Vesicle Invasion:	Absent
Perineural Invasion:	Present
Venous (Large Vessel) Invasion (V):	Present

[page 4 of 4]
Lymphatic (Small Vessel) Invasion (L): Absent
Additional Pathologic Findings: High-grade prostatic
intraepithelial neoplasia (PIN)

** Electronically Signed Out **

M.D.

Attending Pathologist

The attending pathologist whose signature appears on this
report has reviewed the diagnostic slides, and has edited
the gross and microscopic portions of the report in rendering the
final diagnosis.

ICD9 Codes: A-H: 185

SNOMED:

Slides: A-2, B-2, C-2, D-2, E-2, F-1, G-26, H-6
Resulting Agency

rior Malignancy History		
ase is (circle):	QUALIFIED	UNQUALIFIED

8/2/12

Source: NCI Genomic Data Commons file 2495ff33-67cf-4dd3-8da4-73e31a71896a (TCGA-KC-A4BR.E44796E6-0446-4706-8B8F-A21D417EAB43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).